Surgical pathology report (de-identified scan), TCGA case TCGA-55-6971, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6971-01A (Primary Tumor).

[page 1 of 2]
PHYSICIAN INFORMATION

SPECIMEN INFORMATION

Collected:

Received:

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Lymph node, inferior pulmonary ligament, excision:

No metastatic carcinoma identified in one anthracotic lymph node (0/1).

B. Lymph node, hilar; excision:

No metastatic carcinoma identified in three anthracotic lymph nodes (0/3).

C. Lymph node, interlobar; excision:

No metastatic carcinoma identified in four anthracotic lymph nodes (0/4).

D. Lung, left lower lobe; lobectomy:

Specimen type, procedure:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Location of tumor: Left lower lobe.
3. Size: 3.3 x 3.0 x 2.7 cm.
4. Grade: Moderately to poorly differentiated.
5. Pleural invasion: No.
6. Lymphovascular space invasion: No.

Surgical Margin Status:

1. Tumor distance from bronchial margin: 2.8 cm.
2. Tumor distance from pleural surface: 0.1 cm.

Lymph Node Status

1. Total number of lymph nodes examined: Fourteen.
- a. One inferior pulmonary ligament node, see specimen A.
- b. Three hilar nodes, see specimen B.
- c. Four interlobar nodes, see specimen C.
- d. One peribronchial node.
- e. Two AP window lymph node, see specimen E.
- f. Three subcarinal nodes, see specimen F.
2. Total number of lymph nodes containing metastatic carcinoma: Zero (0/14).

Other:

1. pTNM stage: pT2 N0 Mx.

E. Lymph node, AP window; excision:

No metastatic carcinoma identified in two lymph nodes (0/2).

F. Lymph node, subcarinal; excision:

No metastatic carcinoma identified in three lymph nodes (0/3).

CLINICAL INFORMATION

[page 2 of 2]
CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Left lower lobe lung cancer, biopsy proven at (

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Inferior pulmonary ligament lymph node
- B. Hilar lymph node
- C. Interlobar lymph node
- D. Left lower lobe node
- E. AP window lymph node
- F. Subcarinal lymph node

SPECIMEN DATA

GROSS DESCRIPTION:

A. The first container A is labeled , is, #1. The specimen consists of a gray tan nodule measuring 3.0 x 1.0 x 0.5 cm consistent with a lymph node. The lymph node is bisected and entirely submitted in a single cassette

B. The second container B is labeled #2. The specimen consists of a brown tan tissue that on sectioning reveals three possible lymph nodes measuring from 0.9 to 1.5 cm. The lymph nodes are entirely submitted in a single cassette

C. The third container C is labeled #3. The specimen consists of five brown tan nodules consistent with lymph nodes, 0.5 to 2.5 cm in greatest dimension consistent with probable lymph nodes. The lymph nodes are entirely submitted in cassettes as follows: four probable lymph nodes--1; one probable lymph node bisected--2.

D. The fourth container D is labeled , left lower lobe. The specimen consists of a lung lobectomy specimen measuring 16.0 x 11.0 x 3.0 cm and weighs 132 grams. The pleural surface is brown tan to gray tan anthracotic. The pleura has been inked. Sectioning reveals a circumscribed gray tan slightly anthracotic mass measuring 3.3 x 3.0 x 2.7 cm that is within 0.1 cm of the pleural margin and 2.8 cm of the bronchial margin. There is no stapled edge identified. The surrounding lung tissue is brown tan to red tan and spongy. There are no other lesions identified. There are no lymph nodes noted within the peribronchial soft tissue. Received with the specimen are two cassettes, one green and one yellow, labeled as follows: sections from the mass--1 to 4; bronchial and vascular margin--5; representative sections from the uninvolved lung--6.

E. The fifth container E is labeled , #5. The specimen consists of four brown anthracotic nodules consistent with lymph nodes measuring from 0.5 to 2.5 cm. The lymph nodes are entirely submitted in cassettes as follows: three probable nodes--1; one probable node bisected--2 and 3.

F. The sixth container F is labeled , #6. The specimen consists of a brown tan portion of soft tissue measuring 3.0 x 1.0 x 0.5 cm that on sectioning reveals three possible lymph nodes measuring from 0.5 to 1.3 cm. The lymph nodes are entirely submitted in cassettes as follows: one probable node bisected--1; two probable nodes--2.

Source: NCI Genomic Data Commons file b9367d31-9243-419a-8c11-b7ab895740a8 (TCGA-55-6971.C270E56A-DFC6-41A5-9CFC-3C302C4CCC13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).